Somatic mutation profile of tumor specimen TCGA-VS-A9V1-01A (aliquot TCGA-VS-A9V1-01A-11D-A42O-09) from TCGA case TCGA-VS-A9V1, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 46.5 years (17,001 days).
Specimen TCGA-VS-A9V1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01e75c3b-a2b6-40c8-8043-5336c5090104.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9V1-10A (Blood Derived Normal), aliquot TCGA-VS-A9V1-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c343c5b-9915-41d0-8185-43d7b6f66eea

The open-access MAF lists 184 somatic variants for this specimen: 127 protein-altering or splice-affecting, 48 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 48, Nonsense Mutation 9, Intron 4, Splice Site 3, 3'UTR 2, Splice Region 2, Frame Shift Del 1, In Frame Del 1, 5'UTR 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 7/36 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PHKA2 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs797044877, CM991038, COSV101177128; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TACR3 | c.737+1G>A p.X246_splice | Splice Site (SNP) | VAF 19/71 reads (27%) | catalogued as rs760022956, CS104228, COSV59199949; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100068625; called by muse, mutect2, varscan2
- ACAN | c.6292G>A p.E2098K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV100718259, COSV61371092; called by muse, mutect2, varscan2
- ACSL6 | c.1450C>A p.L484I (on ENST00000379240; = p.L509I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.58); catalogued as COSV99733823; called by muse, mutect2, varscan2
- ADAMTS19 | c.2897A>T p.Y966F | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.211); catalogued as COSV99179027; called by muse, mutect2, varscan2
- ADAMTS9 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV55780508; called by muse, mutect2, varscan2
- ADCY3 | c.603C>A p.H201Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99568373; called by muse, varscan2
- AHCTF1 | c.4357G>A p.E1453K (on ENST00000366508; = p.E1427K on NM_015446.5) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV100403827; called by muse, mutect2, varscan2
- ALAS1 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV100050356; called by muse, mutect2, varscan2
- AMOT | c.2240G>T p.R747M (on ENST00000371959 / NM_001113490.1; = p.R338M on NM_133265.3) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100495127; called by muse, mutect2, varscan2
- ANKS1B | c.138C>G p.I46M | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.539); catalogued as COSV100246003; called by muse, mutect2, varscan2
- ARID1B | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs1240706895, COSV99269746; called by muse, mutect2, varscan2
- ASXL2 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55462305; called by muse, mutect2, varscan2
- ATP2B2 | c.1629C>T p.P543= (on ENST00000352432; = p.P509= on NM_001683.5) | Splice Region (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100660002, COSV59492535; called by muse, mutect2, varscan2
- ATP2B2 | c.12G>C p.M4I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as rs1251132863, COSV100660003; called by muse, mutect2, varscan2
- BMX | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100564489; called by muse, mutect2, varscan2
- BPGM | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV100790209; called by muse, mutect2, varscan2
- C20orf96 | c.148C>A p.H50N (on ENST00000360321 / NM_153269.3; = p.H49N on NM_080571.1) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100826727; called by muse, mutect2, varscan2
- CABYR | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100510076; called by muse, mutect2, varscan2
- CASZ1 | c.3262C>T p.P1088S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1557462145, COSV100681525; called by muse, mutect2, varscan2
- CCNK | c.149G>C p.R50P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101110426, COSV101110558; called by muse, mutect2, varscan2
- CCR10 | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1176335399, COSV99226515; called by muse, mutect2, varscan2
- CD163 | c.3297G>A p.M1099I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.914); catalogued as COSV63128994; called by muse, mutect2, varscan2
- CDHR1 | c.2429C>A p.T810N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.157); catalogued as rs759646243, COSV100258933; called by muse, mutect2, varscan2
- CHAC2 | c.136-2A>C p.X46_splice | Splice Site (SNP) | VAF 46/143 reads (32%) | catalogued as COSV99712087; called by muse, mutect2, varscan2
- CHRNG | c.642G>C p.K214N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV101263904; called by muse, mutect2, varscan2
- CLDN11 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.628); catalogued as COSV99291048; called by muse, mutect2, varscan2
- CNTLN | c.1388C>A p.S463* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99264353; called by muse, mutect2, varscan2
- CORO7 | c.86G>A p.G29E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs1270698708, COSV52028057; called by muse, mutect2, varscan2
- CPA1 | c.186del p.I63Sfs*27 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as COSV50571460; called by mutect2, pindel, varscan2
- CYP2A6 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs1355151029, COSV56537500; called by muse, mutect2, varscan2
- DCAF8 | c.386C>A p.S129* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100470504; called by muse, mutect2
- DHH | c.679G>C p.A227P | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV99908859; called by muse, mutect2
- DMXL2 | c.582G>C p.L194F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99196430; called by muse, mutect2, varscan2
- DOCK9 | c.4144G>T p.D1382Y (on ENST00000376460 / NM_001366676.2; = p.D1383Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV100239473; called by muse, mutect2, varscan2
- DUSP26 | c.278A>C p.N93T | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99823482; called by muse, mutect2, varscan2
- DYSF | c.2762C>T p.S921L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs535323489, COSV50278983; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECHDC2 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1285675770, COSV100597799, COSV64300701, COSV64301721; called by muse, mutect2, varscan2
- EFCAB7 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100937693; called by muse, mutect2, varscan2
- EFHC2 | c.1976T>A p.I659N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100637954; called by muse, mutect2, varscan2
- EGR3 | c.466G>C p.E156Q | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.89); catalogued as COSV100416206; called by muse, mutect2, varscan2
- EIF3A | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100974638; called by muse, mutect2, varscan2
- ENDOD1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.107); catalogued as COSV99566598; called by muse, mutect2, varscan2
- EPB41L2 | c.2393G>T p.S798I | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100440855; called by muse, mutect2, varscan2
- ERICH3 | c.3445C>A p.L1149I | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as COSV100444562; called by muse, mutect2, varscan2
- EZH1 | c.557A>C p.Y186S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV101331377; called by muse, mutect2, varscan2
- FANCA | c.960C>A p.F320L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV101224854, COSV66882863; called by muse, mutect2, varscan2
- FANCB | c.1021G>C p.V341L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.024); catalogued as COSV100146574; called by muse, mutect2, varscan2
- FBXL20 | c.754C>A p.L252I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.536); catalogued as COSV99234313; called by muse, mutect2
- FCER2 | c.13C>G p.Q5E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV100689576, COSV60916334; called by muse, mutect2, varscan2
- FIG4 | c.1122C>G p.I374M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as rs1376239309, COSV100019744; called by muse, mutect2, varscan2
- GCAT | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs750055272, COSV99030606; called by muse, mutect2, varscan2
- GMEB1 | c.1623C>G p.I541M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV99603267; called by muse, mutect2, varscan2
- GNMT | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99769793; called by muse, mutect2, varscan2
- GPR158 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100893674; called by muse, mutect2, varscan2
- GPR158 | c.137C>A p.A46D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.077); catalogued as COSV100893675; called by muse, mutect2, varscan2
- GPR171 | c.317C>G p.A106G | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99853446; called by muse, mutect2, varscan2
- H2AC12 | c.113G>A p.G38D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV63616668; called by muse, mutect2, varscan2
- HACL1 | c.1210A>T p.I404F | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100337266; called by muse, mutect2, varscan2
- HDC | c.1902C>G p.I634M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.317); catalogued as COSV99984088; called by muse, mutect2, varscan2
- HOXA2 | c.702G>C p.E234D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99761250; called by muse, mutect2, varscan2
- HRNR | c.355G>C p.E119Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.91); catalogued as COSV100913543; called by muse, mutect2, varscan2
- IFNA8 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV101206908; called by muse, mutect2, varscan2
- IQCN | c.1257C>A p.C419* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as COSV101148725; called by muse, mutect2, varscan2
- IRF2BP1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.888); catalogued as COSV56194283; called by muse, mutect2, varscan2
- ITGA7 | c.896G>T p.G299V (on ENST00000555728; = p.G255V on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV99145981; called by muse, mutect2, varscan2
- JCAD | c.4071G>C p.E1357D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948125; called by muse, mutect2, varscan2
- KCNK1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290249220, COSV100785705; called by muse, mutect2, varscan2
- KCNK6 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.773); catalogued as COSV99649374; called by muse, mutect2, varscan2
- KCNV1 | c.1003C>A p.L335I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1254842489, COSV52087801, COSV99819151; called by muse, mutect2, varscan2
- KIF5C | c.2801C>G p.S934* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101276147; called by muse, mutect2, varscan2
- LARP7 | c.1389G>C p.E463D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV100135178; called by muse, mutect2, varscan2
- LARP7 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV100135182; called by muse, mutect2, varscan2
- LILRB1 | c.1423G>A p.G475S (on ENST00000427581; = p.X438_splice on NM_006669.6) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as rs1477910798, COSV100207353; called by muse, mutect2, varscan2
- LRP1B | c.9181G>A p.D3061N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as rs900350944, COSV67199550; called by muse, mutect2, varscan2
- LRRC25 | c.160C>G p.H54D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV100170544; called by muse, mutect2, varscan2
- LY6E | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV99465095; called by muse, mutect2, varscan2
- MRGPRD | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1049161913, COSV58422812; called by muse, mutect2, varscan2
- MSL3 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV56496819; called by muse, mutect2, varscan2
- MTMR10 | c.2038C>T p.H680Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.808); catalogued as COSV58729400; called by muse, mutect2, varscan2
- NAA16 | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101038347; called by muse, mutect2, varscan2
- NID1 | c.784G>C p.V262L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as COSV99937621; called by muse, mutect2
- NIN | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.637); catalogued as COSV55392062, COSV55399618, COSV99813728; called by muse, mutect2, varscan2
- NLRC3 | c.2837C>G p.T946R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.372); catalogued as COSV100072871; called by muse, mutect2, varscan2
- NOTCH4 | c.4417C>T p.R1473C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1041758474, COSV66679525; called by muse, mutect2, varscan2
- OR2T11 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100424843; called by muse, mutect2, varscan2
- OR2V2 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100080147; called by muse, mutect2, varscan2
- OR4N5 | c.328G>C p.G110R | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100374112, COSV61321126; called by muse, mutect2, varscan2
- PACSIN3 | c.1179G>C p.M393I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV100096387; called by mutect2, varscan2
- PEX5L | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs985145336, COSV55849613, COSV99828953; called by muse, mutect2, varscan2
- PHF24 | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as COSV54276986, COSV99646110; called by muse, mutect2
- PHKA2 | c.2496G>C p.K832N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101177125; called by muse, mutect2, varscan2
- PLEKHG5 | c.1024G>A p.E342K (on ENST00000400915 / NM_001042663.3; = p.E305K on NM_020631.6) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.197); catalogued as rs750943470, COSV100556813; ClinVar: uncertain significance; called by muse, varscan2
- PLG | c.983A>G p.D328G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV99804741; called by muse, mutect2, varscan2
- POLG | c.1221C>G p.F407L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.368); catalogued as COSV99174817; called by muse, mutect2, varscan2
- PPP2R1B | c.846C>T p.L282= | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100232208; called by muse, mutect2, varscan2
- PTCD3 | c.938G>A p.W313* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as COSV99606383; called by muse, mutect2, varscan2
- PTPRD | c.3197G>A p.R1066Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.479); catalogued as rs749208350, COSV61942144, COSV61962493; called by muse, mutect2, varscan2
- RAD17 | c.1846G>A p.E616K (on ENST00000380774 / NM_133339.2; = p.E605K on NM_002873.1) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV99281536; called by muse, mutect2, varscan2
- SCAMP3 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.233); catalogued as COSV100226753; called by muse, mutect2
- SEMA3G | c.1879-1G>C p.X627_splice | Splice Site (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99202370; called by muse, mutect2, varscan2
- SGCA | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs763372958, COSV100006726; called by muse, mutect2, varscan2
- SLC18A2 | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV100041726; called by muse, mutect2, varscan2
- SLC44A3 | c.556T>G p.C186G (on ENST00000271227 / NM_001114106.3; = p.C138G on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54729891, COSV99598252; called by muse, mutect2, varscan2
- SMC6 | c.1744C>G p.P582A | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100705148; called by muse, mutect2, varscan2
- SOCS3 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as COSV100434504; called by muse, mutect2, varscan2
- TAF1 | c.2926C>T p.R976C (on ENST00000373790 / NM_138923.4; = p.R997C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52108288; called by muse, mutect2, varscan2
- TBC1D17 | c.123C>G p.D41E | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.596); catalogued as COSV99680691; called by muse, mutect2, varscan2
- TCIRG1 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.142); catalogued as COSV99693412; called by muse, mutect2, varscan2
- THSD7A | c.2593C>T p.R865* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as rs1191902327, COSV70269752; called by muse, mutect2, varscan2
- TIMM10B | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV54448161, COSV99601548; called by muse, mutect2, varscan2
- TMED9 | c.696G>C p.K232N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99219047; called by muse, mutect2, varscan2
- TPRG1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV100800495; called by muse, mutect2, varscan2
- TRPM6 | c.5270C>T p.S1757F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764032925, COSV100666467; called by muse, mutect2, varscan2
- TUBGCP2 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99427837; called by muse, mutect2
- UBC | c.1203C>A p.D401E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV100299008; called by muse, mutect2, varscan2
- UBR4 | c.1351A>G p.T451A | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100920991; called by muse, mutect2, varscan2
- UBR7 | c.800C>G p.S267C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.353); catalogued as COSV99184277; called by muse, mutect2, varscan2
- UST | c.433A>G p.T145A | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV100820010; called by muse, mutect2, varscan2
- WDR81 | c.3469G>A p.E1157K (on ENST00000409644 / NM_001163809.2; = p.E106K on NM_152348.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1459817590, COSV100488949; called by muse, mutect2, varscan2
- WSCD2 | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99774709; called by muse, mutect2, varscan2
- ZPBP2 | c.245G>C p.G82A (on ENST00000348931 / NM_199321.3; = p.G60A on NM_198844.3) | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV100818528, COSV62375726; called by muse, mutect2, varscan2
- LRP5 | c.2221_2244del p.R741_D748del | In Frame Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- SBF1 | c.3072dup p.A1025Cfs*63 | Frame Shift Ins (INS) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- APOA4 | c.723G>C p.L241= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1163265797, COSV100759336, COSV100759359; called by muse, mutect2, varscan2
- ASPM | c.5436C>T p.Y1812= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs760048482, COSV99660492; called by muse, mutect2, varscan2
- BSN | c.9747T>A p.P3249= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99608658; called by muse, mutect2, varscan2
- BTAF1 | c.3213C>G p.L1071= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV99795419; called by muse, mutect2, varscan2
- CAPRIN2 | c.1245G>A p.K415= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs753759832, COSV99195520; called by muse, mutect2, varscan2
- CC2D2B | c.36G>A p.K12= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100729456, COSV100729494; called by muse, mutect2, varscan2
- CD63 | c.99C>G p.V33= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99141724, COSV99141802; called by muse, mutect2, varscan2
- CELSR3 | c.87C>G p.L29= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV99373568, COSV99373716; called by muse, mutect2, varscan2
- CFAP61 | c.2760C>T p.F920= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV99845225; called by muse, mutect2, varscan2
- CLEC3B | c.264G>A p.T88= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs1414917803, COSV56109402; called by muse, mutect2, varscan2
- CLMP | c.117G>A p.L39= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV101507399; called by muse, mutect2, varscan2
- CLSTN2 | c.2037C>T p.T679= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs201108538, COSV71726316; called by muse, mutect2, varscan2
- CTBS | c.1131C>G p.V377= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99759755; called by muse, mutect2, varscan2
- CYB5R3 | c.675C>G p.L225= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100677894; called by muse, mutect2, varscan2
- DNAJA3 | c.117G>T p.L39= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99276721; called by muse, mutect2, varscan2
- DUSP7 | c.756C>G p.L252= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs946377556, COSV99623505; called by muse, mutect2, varscan2
- GFPT2 | c.723G>A p.R241= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV99517754; called by muse, mutect2, varscan2
- GLDC | c.2412A>G p.P804= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs1008088665, COSV100394225; called by muse, mutect2, varscan2
- GOLGA3 | c.3081C>T p.L1027= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs754062117, COSV99207469; called by muse, mutect2, varscan2
- HDC | c.1419C>T p.L473= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99984090; called by muse, mutect2, varscan2
- HOXA10 | c.435G>T p.P145= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV99385500; called by muse, mutect2, varscan2
- HYDIN | c.2256C>A p.P752= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV55486140, COSV99862930; called by muse, mutect2, varscan2
- KDM5B | c.4158G>A p.V1386= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99350727; called by muse, mutect2, varscan2
- MICALL2 | c.2673C>G p.S891= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99875991; called by muse, mutect2, varscan2
- MSN | c.516C>T p.I172= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100814239; called by muse, mutect2, varscan2
- NDC1 | c.870C>G p.L290= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as COSV99323666; called by muse, mutect2, varscan2
- OR6C2 | c.258G>A p.G86= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100498711; called by muse, mutect2, varscan2
- PADI4 | c.555G>A p.L185= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs149577899; called by muse, mutect2, varscan2
- PDCD11 | c.3285G>A p.G1095= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs766017303, COSV100874357; called by muse, mutect2, varscan2
- PNLIP | c.63C>T p.Y21= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs765217829, COSV65040603; called by muse, mutect2, varscan2
- PPP3CC | c.972C>T p.V324= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV99252176; called by muse, mutect2, varscan2
- PRPSAP1 | c.645C>G p.S215= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV100221726; called by muse, mutect2, varscan2
- PTBP3 | c.75C>T p.I25= | Silent (SNP) | VAF 45/139 reads (32%) | catalogued as COSV99270272; called by muse, mutect2, varscan2
- PTGIS | c.1164C>T p.F388= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV54839301; called by muse, mutect2
- RMDN2 | c.960C>T p.S320= (on ENST00000354545 / NM_001322212.2; = p.S498= on NM_144713.5) | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV99307799; called by muse, mutect2, varscan2
- ROBO3 | c.3210G>C p.L1070= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV101185066; called by muse, mutect2, varscan2
- SCAMP3 | c.555C>T p.C185= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100226750; called by muse, varscan2
- SERPINA12 | c.892T>C p.L298= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100369711; called by muse, mutect2, varscan2
- SIDT2 | c.1944C>T p.L648= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99637792; called by muse, mutect2, varscan2
- SKIDA1 | c.246C>T p.L82= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as rs771896442, COSV101481311; called by muse, mutect2, varscan2
- SLC46A1 | c.1239C>G p.L413= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99134999; called by muse, mutect2, varscan2
- SLC4A5 | c.2406C>G p.P802= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100697711; called by muse, mutect2, varscan2
- STARD13 | c.3123C>A p.L1041= (on ENST00000336934 / NM_001243476.3; = p.L923= on NM_052851.3) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV55230791, COSV55236311, COSV99715985; called by muse, mutect2, varscan2
- TMEM266 | c.54A>T p.G18= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV101189625, COSV66378774; called by muse, mutect2, varscan2
- TMUB1 | c.309C>G p.L103= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs764256756, COSV52540279, COSV99879796; called by muse, mutect2, varscan2
- TUBB1 | c.819C>T p.L273= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99414093; called by muse, mutect2, varscan2
- XDH | c.1275C>T p.S425= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV65149132; called by muse, mutect2, varscan2
- ZNF827 | c.1080A>G p.K360= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101061414; called by muse, mutect2, varscan2
- HSPA2 | chr14:64531898 G>A | 5'Flank (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100704143; called by muse, mutect2, varscan2
- JMJD1C | c.333+7321C>G | Intron (SNP) | VAF 7/27 reads (26%) | catalogued as rs1333102194, COSV101232426; called by muse, mutect2, varscan2
- LARP7 | c.1142+564C>T | Intron (SNP) | VAF 14/49 reads (29%) | catalogued as rs756098665, COSV60521779; called by muse, mutect2, varscan2
- MIR376A1 | n.10G>C | RNA (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- NINJ2 | c.-140G>A | 5'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as rs1182824102, COSV100523162; called by muse, mutect2
- RMDN2 | c.452+21713G>A | Intron (SNP) | VAF 8/22 reads (36%) | catalogued as COSV99307796; called by muse, mutect2, varscan2
- RPGR | c.2520+1449G>A | Intron (SNP) | VAF 24/59 reads (41%) | catalogued as COSV100140058; called by muse, mutect2, varscan2
- SDC1 | c.*477C>A | 3'UTR (SNP) | VAF 12/38 reads (32%) | catalogued as COSV54339623, COSV99587185; called by muse, mutect2, varscan2
- SMIM29 | c.*4G>C | 3'UTR (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100102854; called by muse, mutect2, varscan2
